Surgical pathology report (de-identified scan), TCGA case TCGA-19-2631, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2631-01A (Primary Tumor).

19-2631

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

- A. RIGHT FRONTAL LOBE OF BRAIN, TUMOR, BIOPSY:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
- B. RIGHT FRONTAL LOBE OF BRAIN, TUMOR, REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
- C. RIGHT FRONTAL LOBE OF BRAIN, "INFERIOR WHITE MATTER", REMOVAL:
-- GLIOBLASTOMA MULTIFORME (TWO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

- A. Microscopic diagnosis: Glioblastoma.

Clinical History:

r frontal tumor

Specimens Submitted As:

A:TUMOR
B:RF TUMOR
C:INT WM

Gross Description:

A. Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "tumor" consists of multiple irregular tan-white and red fragments of soft tissue, 2.5 x 1.5 x 0.6 cm in aggregate. Touch preparations are performed. A portion of the specimen is submitted for frozen section analysis. A portion of the specimen is submitted for [REDACTED]. The remainder of the specimen is entirely submitted for permanent sections in two cassettes.

B: Received fresh, labeled with patient's name, number, and "B-RF tumor", are multiple pink-tan, irregular, soft, cerebriform tissue fragments measuring 6.0 x 5.0 x 3.0 cm in aggregate. On section, the fragments are light tan to focally red-brown. Representative sections are submitted in six cassettes. A portion of tissue was given to [REDACTED]

C: Received in formalin, labeled with patient's name, number, and "C-inf WM", are multiple pink-tan to light tan, irregular, soft, cerebriform tissue fragments measuring 5.3 x 4.2 x 2.0 cm in aggregate. On section, the fragments are light tan to focally red-brown. Representative sections are submitted in five cassettes.

Source: NCI Genomic Data Commons file 21b8fe59-8d03-42b0-a8ed-776da81abb05 (TCGA-19-2631.846F6219-3E04-4A51-BB52-2239085973B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).